Somatic mutation profile of tumor specimen TCGA-DX-A8BL-01A (aliquot TCGA-DX-A8BL-01A-11D-A417-09) from TCGA case TCGA-DX-A8BL, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 59.5 years (21,728 days).
Specimen TCGA-DX-A8BL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34825326-d0a4-42f6-a6cd-d52b64b59642.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A8BL-10A (Blood Derived Normal), aliquot TCGA-DX-A8BL-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3cbdb7ba-d930-4b13-b0cf-d378f0cb6068

The open-access MAF lists 93 somatic variants for this specimen: 66 protein-altering or splice-affecting, 22 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 22, Nonsense Mutation 3, Intron 2, In Frame Del 2, Splice Site 1, RNA 1, Splice Region 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.807_809del p.F270del | In Frame Del (DEL) | VAF 8/13 reads (62%) | hotspot (GDC flag); called by mutect2, varscan2
- ADAMDEC1 | c.902A>G p.K301R | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.597); catalogued as COSV99836029; called by muse, mutect2
- ADGRE1 | c.83C>A p.P28Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99165122; called by muse, mutect2, varscan2
- ARFGEF3 | c.2907A>T p.K969N | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.395); catalogued as COSV99293266; called by muse, mutect2, varscan2
- AXDND1 | c.1208C>G p.A403G | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV100858349; called by muse, mutect2, varscan2
- BTBD16 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs753410399, COSV99584727; called by muse, mutect2, varscan2
- C4BPA | c.943A>T p.R315W | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV100891197; called by muse, varscan2
- C7orf26 | c.44G>A p.S15N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1194665553, COSV100253909; called by muse, mutect2, varscan2
- CALCR | c.809C>A p.T270N (on ENST00000649521 / NM_001164737.2; = p.T254N on NM_001742.4) | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100810500; called by muse, mutect2, varscan2
- CCDC54 | c.512A>G p.Y171C | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV99660184; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3057C>A p.D1019E | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV100575371; called by muse, mutect2, varscan2
- CEACAM20 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV100386864; called by muse, mutect2, varscan2
- CHST1 | c.722C>A p.A241D | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100346202; called by muse, mutect2, varscan2
- CLYBL | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 43/69 reads (62%) | catalogued as rs1217436926, COSV100185231, COSV59216798; called by muse, mutect2, varscan2
- CPA5 | c.626C>T p.T209I | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.38); PolyPhen benign (0.182); catalogued as COSV100812293; called by muse, varscan2
- CYP2C18 | c.1112C>A p.T371N | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.096); catalogued as rs893658493, COSV99608492; called by muse, mutect2, varscan2
- DCAF4L2 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV60480325; called by muse, mutect2
- DCLK2 | c.1124G>A p.S375N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1488061745, COSV99651915; called by muse, mutect2, varscan2
- DSG4 | c.2671C>T p.Q891* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100355788; called by muse, mutect2, varscan2
- EPHA8 | c.1274C>A p.P425H | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99384694; called by muse, mutect2, varscan2
- ETV3L | c.962A>T p.K321M | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV101485579; called by muse, mutect2, varscan2
- EVC2 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100185784; called by muse, mutect2, varscan2
- FAM151A | c.576-1G>T p.X192_splice | Splice Site (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100156687; called by muse, mutect2
- FCER2 | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as COSV100689559, COSV60916152; called by muse, mutect2
- FER1L6 | c.2837C>G p.S946C | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.822); catalogued as COSV101205783; called by muse, mutect2, varscan2
- GREM2 | c.135G>T p.W45C | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.643); catalogued as COSV100547494; called by muse, mutect2, varscan2
- GREM2 | c.134G>T p.W45L | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0.05); catalogued as COSV100547498; called by muse, mutect2, varscan2
- IL23A | c.161T>A p.M54K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV99950652; called by muse, mutect2, varscan2
- KCNJ6 | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99899686; called by muse, mutect2, varscan2
- KIAA1109 | c.1727C>T p.T576I | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1324727494, COSV99158374; called by muse, mutect2, varscan2
- KIF20B | c.2424C>G p.N808K (on ENST00000371728 / NM_001284259.2; = p.N768K on NM_016195.4) | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.073); catalogued as rs189443463, COSV53314488, COSV99589904; called by muse, mutect2, varscan2
- MARCHF9 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.613); catalogued as rs372403968; called by muse, mutect2
- MARK1 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs758630636, COSV100857182; called by muse, mutect2, varscan2
- MAST2 | c.2027A>G p.D676G | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); catalogued as COSV100788061; called by muse, mutect2, varscan2
- MS4A2 | c.274A>C p.I92L | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV99627212; called by muse, mutect2, varscan2
- MYH10 | c.5702G>A p.R1901H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52598072; called by muse, mutect2, varscan2
- NAPG | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.723); catalogued as COSV100529764; called by muse, mutect2
- NOL12 | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs746027481, COSV100767141; called by muse, mutect2, varscan2
- NUMA1 | c.6223A>C p.K2075Q | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99474651; called by muse, mutect2, varscan2
- OR2T12 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as rs760289314, COSV100527726; called by muse, mutect2, varscan2
- OSTN | c.349G>T p.G117C | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766806506, COSV100174223; called by muse, mutect2, varscan2
- PADI2 | c.1795G>A p.G599S | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100971904; called by muse, mutect2, varscan2
- PAPPA | c.2302C>T p.P768S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV100073852; called by muse, mutect2, varscan2
- PARP10 | c.1142C>A p.P381H | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV100477967; called by muse, mutect2, varscan2
- PEG3 | c.196A>G p.K66E | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs1368056074, COSV99688646; called by muse, mutect2, varscan2
- PIK3CG | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as rs1462539802, COSV63248803; called by muse, mutect2, varscan2
- PRAG1 | c.1619A>G p.E540G | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100422129; called by muse, mutect2, varscan2
- PSMC2 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV99485267; called by muse, mutect2, varscan2
- PTPRO | c.832A>T p.N278Y | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.687); catalogued as COSV99840380; called by muse, mutect2, varscan2
- RAB27A | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as rs151048993; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAI1 | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV99883908; called by muse, mutect2
- SEMA4D | c.1412A>G p.E471G | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as rs772201723, COSV100358280; called by muse, mutect2, varscan2
- SERPINB13 | c.470A>T p.N157I | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV99501000; called by muse, mutect2, varscan2
- SIDT1 | c.1424A>G p.N475S | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99333772; called by muse, mutect2, varscan2
- SLC22A25 | c.202A>T p.S68C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100123577; called by muse, mutect2, varscan2
- SLC25A47 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as rs759660610, COSV62309674; called by muse, mutect2, varscan2
- SLC28A2 | c.591G>T p.V197= | Splice Region (SNP) | VAF 10/48 reads (21%) | catalogued as rs745310438, COSV100754686; called by muse, varscan2
- SLC9B1 | c.691C>G p.P231A | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99599531; called by muse, mutect2
- TRPM6 | c.4388C>T p.T1463I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.178); catalogued as COSV100666243; called by muse, mutect2, varscan2
- ZNF225 | c.1783C>G p.P595A | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV99489428; called by muse, mutect2
- ZNF507 | c.2690C>G p.S897C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100321797; called by mutect2, varscan2
- ZNF768 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100776227, COSV63320480; called by muse, mutect2, varscan2
- ZNF81 | c.1913A>G p.Y638C | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100095571; called by muse, mutect2, varscan2
- FOXD4L4 | c.64G>T p.G22W | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- KIR2DL4 | c.813C>A p.S271R (on ENST00000396284; = p.S232R on NM_001080770.2) | Missense Mutation (SNP) | VAF 30/269 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.842); called by muse, varscan2
- SYDE1 | c.2047_2052del p.S683_E684del | In Frame Del (DEL) | VAF 13/88 reads (15%) | called by mutect2, pindel, varscan2
- AKAP1 | c.1983A>G p.Q661= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs562043469, COSV100027912; called by muse, mutect2, varscan2
- ANO2 | c.1791C>T p.G597= (on ENST00000356134 / NM_001278597.3; = p.G601= on NM_001278596.3) | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs373059086; called by muse, mutect2, varscan2
- ARHGEF26 | c.1656C>A p.S552= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV100726445, COSV100726532; called by muse, mutect2, varscan2
- BEND7 | c.108C>G p.P36= | Silent (SNP) | VAF 14/75 reads (19%) | called by muse, mutect2, varscan2
- CLPSL1 | c.177G>T p.S59= | Silent (SNP) | VAF 28/268 reads (10%) | catalogued as COSV100870178, COSV65815179; called by muse, mutect2, varscan2
- CYSLTR1 | c.261C>A p.G87= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100964724; called by mutect2, varscan2
- DCAF8L1 | c.1761C>T p.S587= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as rs756062581, COSV101491450; called by muse, mutect2, varscan2
- HMCN1 | c.11841G>C p.L3947= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV99628298; called by muse, mutect2, varscan2
- IGF2R | c.1467G>T p.L489= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100807297; called by mutect2, varscan2
- KNDC1 | c.2952C>A p.R984= | Silent (SNP) | VAF 26/146 reads (18%) | catalogued as COSV100464525; called by muse, mutect2, varscan2
- MED12L | c.3148C>T p.L1050= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as COSV99852755; called by muse, mutect2, varscan2
- OR6C75 | c.486G>T p.L162= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100595321; called by muse, mutect2, varscan2
- PCDHA6 | c.468C>T p.G156= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV100972244; called by muse, mutect2, varscan2
- PCDHA8 | c.921T>C p.N307= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as COSV100970669; called by muse, mutect2, varscan2
- PCDHB15 | c.318C>T p.F106= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV99178903; called by muse, mutect2, varscan2
- PKHD1L1 | c.11685C>T p.Y3895= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as COSV101006021, COSV65754470; called by muse, mutect2, varscan2
- PRDM11 | c.147C>T p.A49= (on ENST00000530656 / NM_001359633.1; = p.A15= on NM_001256695.1) | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs373948099, COSV99770655; called by muse, mutect2, varscan2
- PROSER3 | c.1386G>A p.R462= | Silent (SNP) | VAF 24/176 reads (14%) | catalogued as rs1487768096, COSV99994535; called by muse, mutect2, varscan2
- RALGAPA2 | c.1206C>G p.V402= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV52486329, COSV99173537; called by muse, mutect2, varscan2
- STRN | c.702C>T p.F234= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV99815209; called by muse, mutect2, varscan2
- TBC1D1 | c.591C>T p.I197= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs748870275, COSV54716884; called by muse, mutect2, varscan2
- WNK1 | c.6498C>T p.T2166= (on ENST00000315939 / NM_018979.4; = p.T1918= on NM_014823.3) | Silent (SNP) | VAF 50/112 reads (45%) | catalogued as COSV100267180; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821150 C>T | 3'Flank (SNP) | VAF 40/56 reads (71%) | called by muse, mutect2, varscan2
- CLLU1 | n.905C>A | RNA (SNP) | VAF 10/74 reads (14%) | catalogued as COSV101029202; called by muse, mutect2, varscan2
- MLLT1 | c.*1C>A | 3'UTR (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99398000; called by muse, mutect2, varscan2
- MROH8 | c.370+2492C>T | Intron (SNP) | VAF 12/98 reads (12%) | catalogued as COSV99457102; called by muse, mutect2, varscan2
- PRKG1 | c.935+170C>T | Intron (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
